Somatic mutation profile of tumor specimen 0DQHB7 from CCDI case PBCEZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,592 days).
Specimen 0DQHB7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b9db95c-0c3c-4e1f-b051-1ed4939fbd55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1635310c-b49a-445e-8f29-c70bec51ea8f

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, 5'UTR 1, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 112/444 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs952259101; called by muse, mutect2, varscan2
- FBXL17 | c.883T>G p.C295G | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); called by mutect2, varscan2
- FLG | c.9131A>G p.H3044R | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GAPVD1 | c.2619C>G p.N873K (on ENST00000394104; = p.N900K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MCM2 | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEF2B | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR8B2 | c.166C>G p.H56D | Missense Mutation (SNP) | VAF 138/538 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2
- DNAH7 | c.6801C>T p.S2267= | Silent (SNP) | VAF 96/336 reads (29%) | catalogued as rs759472244, COSV100416551; called by muse, mutect2, varscan2
- COL4A2 | c.1340-649del | Intron (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- DHCR24 | c.-17C>A | 5'UTR (SNP) | VAF 61/221 reads (28%) | called by muse, mutect2, varscan2
- EDN3 | c.53-57C>T | Intron (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100285239; called by muse, mutect2, varscan2
- ZC3H11B | chr1:219609585 G>T | 3'Flank (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
